Somatic mutation profile of tumor specimen C3L-04036-01 (aliquot CPT0228100006) from CPTAC case C3L-04036, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.2 years (29,658 days).
Specimen C3L-04036-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b40a10a2-f860-43c9-9284-effc1487913c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04036-31 (Blood Derived Normal), aliquot CPT0228200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a44288a-a3b0-42d9-ae77-09ba460000d5

The open-access MAF lists 94 somatic variants for this specimen: 61 protein-altering or splice-affecting, 23 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 23, Nonsense Mutation 7, Intron 4, RNA 3, 5'UTR 2, Frame Shift Del 2, Splice Region 2, Splice Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP7 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58699531; called by mutect2, varscan2
- CEP95 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782568738, COSV73609620; called by muse, mutect2, varscan2
- CHRM2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446523872, COSV57777879; called by muse, mutect2, varscan2
- CLEC7A | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs759032825; called by muse, mutect2, varscan2
- COL6A5 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as COSV55211936; called by muse, mutect2, varscan2
- DEFB127 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs992999079; called by muse, mutect2, varscan2
- ESR1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1207112399, COSV52805223; called by muse, mutect2, varscan2
- GATB | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1277497850, COSV99859285; called by muse, mutect2, varscan2
- GRIA1 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139620360; called by muse, mutect2, varscan2
- ISLR2 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs942588357; called by muse, mutect2, varscan2
- MMRN2 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1309090662, COSV64400329; called by muse, mutect2, varscan2
- MUC12 | c.1660A>C p.S554R (on ENST00000379442; = p.S411R on NM_001164462.1) | Missense Mutation (SNP) | VAF 58/998 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs779312444; called by muse, mutect2
- OR4C11 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV56354287; called by muse, mutect2, varscan2
- OTOF | c.3079G>A p.D1027N (on ENST00000272371 / NM_194248.3; = p.D280N on NM_004802.4) | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV55518942; called by muse, mutect2, varscan2
- PAX5 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63908541; called by muse, mutect2, varscan2
- RB1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as CM092254, COSV57305848; called by muse, mutect2, varscan2
- SLC6A3 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760871529, COSV54366392; called by muse, mutect2, varscan2
- STIM2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs760297373; called by muse, mutect2, varscan2
- STRN3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as rs1452994149; called by muse, mutect2, varscan2
- SUPT7L | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as rs773381394; called by muse, mutect2, varscan2
- TCL1A | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as rs1230573004; called by muse, mutect2, varscan2
- TENT5C | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs768215715; called by muse, mutect2, varscan2
- TMPRSS11F | c.553+1G>A p.X185_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | catalogued as rs200354776, COSV62465842; called by muse, mutect2, varscan2
- TUBB8P7 | n.894+4C>T | Splice Region (SNP) | VAF 43/266 reads (16%) | catalogued as rs779083315; called by muse, mutect2, varscan2
- WDFY4 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100303532; called by muse, mutect2, varscan2
- YLPM1 | c.6424C>T p.R2142* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | catalogued as rs1181166717; called by muse, mutect2, varscan2
- ACE | c.2297T>G p.L766R | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFN1 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 115/454 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ASB4 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- C4B | c.3592T>A p.Y1198N | Missense Mutation (SNP) | VAF 292/617 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD2BP2 | c.154del p.E52Rfs*20 | Frame Shift Del (DEL) | VAF 34/185 reads (18%) | called by mutect2, pindel, varscan2
- CD6 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CDH9 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSTF2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSG1 | c.2263T>A p.F755I | Missense Mutation (SNP) | VAF 120/529 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2LI1 | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- F7 | c.316+4A>T | Splice Region (SNP) | VAF 160/618 reads (26%) | called by muse, mutect2, varscan2
- GLB1L3 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1109 | c.10750A>T p.I3584F | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIAA1549L | c.724A>G p.R242G (on ENST00000321505; = p.R539G on NM_012194.3) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRIQ1 | c.1921del p.E641Kfs*16 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- MED12 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- NHS | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- NPHP3 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NXPH1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIH1D2 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, varscan2
- PLB1 | c.2628C>A p.N876K | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEA | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PPP1R14C | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRKDC | c.2982G>A p.W994* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- RPL27 | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- SEC24B | c.3593_3595del p.H1198del | In Frame Del (DEL) | VAF 25/132 reads (19%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.865G>T p.V289F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SNAP91 | c.768A>C p.Q256H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TRIM45 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- USP9Y | c.2078G>T p.C693F | Missense Mutation (SNP) | VAF 101/182 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- VPS4B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- XIRP1 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZBTB37 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 129/511 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF331 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ZNF609 | c.2799G>T p.E933D | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL2 | c.2352C>T p.F784= (on ENST00000370717 / NM_001366005.1; = p.F771= on NM_012302.4) | Silent (SNP) | VAF 61/264 reads (23%) | catalogued as COSV99589354; called by muse, mutect2, varscan2
- APBA3 | c.423C>T p.P141= | Silent (SNP) | VAF 67/258 reads (26%) | called by muse, mutect2, varscan2
- ART5 | c.187C>T p.L63= | Silent (SNP) | VAF 69/358 reads (19%) | catalogued as COSV99167152; called by muse, mutect2, varscan2
- COL6A3 | c.8373C>T p.N2791= | Silent (SNP) | VAF 124/484 reads (26%) | catalogued as rs770214487, COSV55099897, COSV55115014; called by muse, mutect2, varscan2
- EFCAB12 | c.300G>A p.E100= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- FREM3 | c.4878C>T p.D1626= | Silent (SNP) | VAF 66/356 reads (19%) | catalogued as rs997227800; called by muse, mutect2, varscan2
- FRMPD2 | c.2928T>C p.G976= | Silent (SNP) | VAF 22/212 reads (10%) | called by mutect2, varscan2
- GREB1L | c.273C>T p.D91= | Silent (SNP) | VAF 39/184 reads (21%) | catalogued as rs370170442; called by muse, mutect2, varscan2
- HTT | c.6549C>T p.L2183= | Silent (SNP) | VAF 121/527 reads (23%) | catalogued as COSV61864055; called by muse, mutect2, varscan2
- HYAL3 | c.36G>A p.G12= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- KLHL7 | c.591C>T p.D197= (on ENST00000339077 / NM_001031710.3; = p.D149= on NM_018846.5) | Silent (SNP) | VAF 62/280 reads (22%) | catalogued as rs1419265890; called by muse, mutect2, varscan2
- MPL | c.1176C>T p.P392= | Silent (SNP) | VAF 130/486 reads (27%) | catalogued as rs757289947, COSV65245359; called by muse, mutect2, varscan2
- NRIP1 | c.3246A>T p.R1082= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV59658426; called by muse, mutect2, varscan2
- OBSCN | c.15936G>A p.K5312= | Silent (SNP) | VAF 79/279 reads (28%) | called by muse, mutect2, varscan2
- PCDHA2 | c.315C>T p.H105= | Silent (SNP) | VAF 104/539 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | c.636C>T p.I212= | Silent (SNP) | VAF 78/280 reads (28%) | catalogued as rs782395304, COSV50692536; called by muse, mutect2, varscan2
- PEAK1 | c.4473G>A p.R1491= | Silent (SNP) | VAF 82/364 reads (23%) | called by muse, mutect2, varscan2
- RNF186 | c.66C>T p.T22= | Silent (SNP) | VAF 88/348 reads (25%) | catalogued as rs777554238; called by muse, mutect2, varscan2
- RNPC3 | c.1011A>G p.L337= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- SEC14L5 | c.546G>A p.T182= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as rs192935938, COSV99229472; called by muse, mutect2, varscan2
- SLC17A6 | c.1644A>G p.T548= | Silent (SNP) | VAF 45/204 reads (22%) | called by muse, mutect2, varscan2
- TMEM131L | c.1932T>C p.D644= | Silent (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- ZNF728 | c.723A>T p.S241= | Silent (SNP) | VAF 59/281 reads (21%) | called by muse, mutect2, varscan2
- AL035696.1 | n.304del | RNA (DEL) | VAF 62/269 reads (23%) | called by mutect2, pindel, varscan2
- CHCHD2P9 | n.36G>A | RNA (SNP) | VAF 44/226 reads (19%) | called by muse, mutect2, varscan2
- DOLK | c.-14C>T | 5'UTR (SNP) | VAF 113/407 reads (28%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1428A>T | 3'UTR (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- ILDR1 | c.-38G>A | 5'UTR (SNP) | VAF 28/109 reads (26%) | catalogued as rs1345717038, COSV99879074; called by muse, mutect2, varscan2
- KCNK17 | c.689-781T>A | Intron (SNP) | VAF 89/322 reads (28%) | called by muse, mutect2, varscan2
- MKRN1 | c.315-246C>T | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- NLRP7 | c.2810+2875G>A | Intron (SNP) | VAF 88/411 reads (21%) | catalogued as COSV60171886; called by muse, mutect2, varscan2
- PLCH2 | c.2959+655C>T | Intron (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2
- SNORD114-12 | n.3G>T | RNA (SNP) | VAF 58/223 reads (26%) | called by muse, mutect2, varscan2
